Gene-level copy-number profile of tumor specimen TCGA-N9-A4PZ-01A from TCGA case TCGA-N9-A4PZ, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC2; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-N9-A4PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.3a45f6c9-8938-4651-acc5-52d528eebf10.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N9-A4PZ-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/efdf98b3-de63-4ff5-956a-de5c3364d46f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,242; copy number 2: 16,703; copy number 3: 19,480; copy number 4: 14,535; copy number 5: 2,951; copy number 6: 2,517; copy number 7: 1,236; copy number 8: 649; copy number 9: 20; copy number 10: 381; copy number 11: 58; copy number 12: 7; copy number 14: 7; copy number 17: 20.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N9-A4PZ-01A-22D-A28Q-01): tumor purity 0.82, ploidy 6.23, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,014 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,924,740–192,957,713, 884 genes, copy number 7–12 (within-gene range 5–12) (broad region; genes not listed).
- chr1:201,283,452–202,928,636, 63 genes, copy number 8 (broad region; genes not listed).
- chr1:230,642,481–235,650,754, 124 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr3:188,107,072–188,154,057, 2 genes, copy number 9: AC022498.1, LPP-AS2.
- chr3:188,178,543–188,180,812, 1 gene, copy number 9: FLJ42393.
- chr4:3,293,028–3,548,796, 8 genes, copy number 7 (within-gene range 5–7): RGS12, AL645949.1, AL645949.2, HGFAC, AL590235.2, DOK7, LRPAP1, AL590235.1.
- chr6:18,387,350–18,468,870, 1 gene, copy number 7: RNF144B.
- chr6:103,583,135–107,661,306, 54 genes, copy number 7–8 (within-gene range 6–8): AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1.
- chr6:157,381,133–158,919,105, 32 genes, copy number 7 (within-gene range 6–7): ZDHHC14, MIR3692, SNX9, AL391863.2, AL391863.1, SNX9-AS1, HSPE1P26, RNU6-786P, SYNJ2, AL139330.1, SYNJ2-IT1, SERAC1, GTF2H5, TULP4, SRP72P2, AL360169.2, AL360169.3, AL360169.1, RN7SL173P, CACYBPP3, TMEM181, TATDN2P2, MIR7161, DYNLT1, SYTL3, AMZ2P2, MIR3918, EZR, EZR-AS1, OSTCP1, AL627422.2, C6orf99.
- chr8:46,028,804–52,745,843, 96 genes, copy number 7–8 (broad region; genes not listed).
- chr8:53,712,697–56,993,867, 63 genes, copy number 7 (broad region; genes not listed).
- chr8:69,987,415–73,747,708, 61 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:94,895,767–95,116,455, 1 gene, copy number 8 (within-gene range 4–8): NDUFAF6.
- chr8:95,039,617–105,804,539, 210 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:105,662,352–105,737,765, 3 genes, copy number 8: AC103853.1, AC103853.2, RPL12P24.
- chr8:133,325,997–133,644,725, 8 genes, copy number 9: KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1.
- chr15:40,133,768–40,394,246, 22 genes, copy number 7: AC021755.1, BUB1B, PAK6, BUB1B-PAK6, AC020658.4, AC020658.3, AC020658.7, C15orf56, AC020658.6, PLCB2, ANKRD63, AC020658.5, PLCB2-AS1, AC020658.1, AC020658.2, INAFM2, CCDC9B, RNA5SP392, PHGR1, DISP2, AC013356.4, KNSTRN.
- chr19:9,751,993–10,653,844, 58 genes, copy number 8: ZNF846, AC008752.3, UBE2L4, AC008752.1, FBXL12, SNORA70, RPL10P15, UBL5, AC008752.2, PIN1, OLFM2, COL5A3, AC008742.1, RDH8, C3P1, MIR5589, SHFL, AC020931.1, ANGPTL6, PPAN-P2RY11, PPAN, SNORD105, SNORD105B, P2RY11, EIF3G, DNMT1, S1PR2, MIR4322, MRPL4, AC011511.2, AC011511.3, ICAM1, AC011511.5, ICAM4, ICAM5, ZGLP1, AC011511.1, FDX2, AC011511.4, RAVER1, AC114271.1, ICAM3, TYK2, CDC37, MIR1181, PDE4A, KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT.
- chr19:28,602,379–29,093,031, 12 genes, copy number 7: AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1.
- chr19:29,287,011–31,554,803, 36 genes, copy number 7–9 (within-gene range 4–9): AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841.
- chr19:34,837,889–35,813,299, 80 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr19:40,319,536–40,808,418, 28 genes, copy number 8 (within-gene range 5–8): C19orf47, Y_RNA, Y_RNA, PLD3, AC118344.2, MIR6796, HIPK4, PRX, SERTAD1, AC010271.2, SERTAD3, AC010271.1, BLVRB, Metazoa_SRP, SPTBN4, SHKBP1, LTBP4, NUMBL, COQ8B, RNU6-195P, ITPKC, C19orf54, SNRPA, MIA, MIA-RAB4B, RAB4B, RAB4B-EGLN2, AC008537.4.
- chr19:45,527,427–46,196,218, 39 genes, copy number 8 (within-gene range 5–8): OPA3, GPR4, EML2, MIR330, EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B, SNRPD2, QPCTL, FBXO46, AC007191.1, BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2, NOVA2, CCDC61, MIR769, PGLYRP1, AC007785.3, IGFL4, AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2, AC006262.2.
- chr19:50,659,255–51,372,701, 66 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:55,090,914–55,580,848, 47 genes, copy number 10: PPP1R12C, AC010327.8, AC010327.3, MIR7975, TNNT1, TNNI3, AC010327.2, DNAAF3, AC010327.4, AC010327.1, SYT5, PTPRH, AC010327.7, AC010327.5, TMEM86B, AC010327.6, PPP6R1, MIR6804, MIR6802, MIR6803, HSPBP1, BRSK1, AC020922.2, TMEM150B, AC020922.4, KMT5C, COX6B2, AC020922.1, FAM71E2, IL11, TMEM190, AC020922.3, TMEM238, RPL28, MIR6805, UBE2S, SHISA7, ISOC2, C19orf85, AC008735.5, AC008735.3, ZNF628, NAT14, SSC5D, SBK2, SBK3, ZNF579.
- chr20:32,005,671–32,031,591, 1 gene, copy number 7 (within-gene range 4–7): AL031658.1.
- chr20:32,010,438–32,439,319, 14 genes, copy number 7 (within-gene range 4–7): CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.

Autosomal genes at a single copy (total copy number 1): 1,242. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
